Somatic mutation profile of tumor specimen MP2PRT-PATZUM-TBP1-A (aliquot MP2PRT-PATZUM-TBP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATZUM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,424 days).
Specimen MP2PRT-PATZUM-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e65470da-4a4a-4fbd-b9c3-d3e7a2135c84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZUM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZUM-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b68ce49-8dd0-4996-949a-92d753a95f9b

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD8 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 22/583 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs1344518491; called by muse, mutect2
- CNPY4 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs751483119; called by muse, mutect2, varscan2
- H1-4 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/646 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1276316143, COSV56803254, COSV56803481; called by muse, mutect2
- MCHR1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs867850290; called by muse, mutect2, varscan2
- APCS | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHSY3 | c.2036A>T p.N679I | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FMO2 | c.1215G>T p.M405I | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2
- MEX3B | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NR3C1 | c.2081T>G p.I694S | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPATA31A7 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 49/994 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2
- CEP152 | c.4554A>T p.G1518= (on ENST00000380950 / NM_001194998.2; = p.G1462= on NM_014985.4) | Silent (SNP) | VAF 11/358 reads (3%) | called by muse, mutect2
- NR3C1 | c.2082C>A p.I694= | Silent (SNP) | VAF 12/398 reads (3%) | called by muse, mutect2
- POU3F2 | c.186C>T p.I62= | Silent (SNP) | VAF 18/450 reads (4%) | called by muse, mutect2
- ASB10 | chr7:151187570 C>G | 5'Flank (SNP) | VAF 18/700 reads (3%) | called by muse, mutect2
